FM case AD7400 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Specialized Gonadal Neoplasms; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/bc2b82f8-85bd-46d2-b004-6c5511605619

Female, 76.8 years: Granulosa cell tumor, NOS (ICD-O-3 8620/1) of the ovary; metastasis biopsied or resected from the colon. Tumor nuclei on the sequenced sample's slide: 90% (pathologist estimate recorded by GDC). Sample type: Metastatic.
